Somatic mutation profile of tumor specimen C3N-02185-01 (aliquot CPT0168590006) from CPTAC case C3N-02185, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.9 years (22,613 days).
Specimen C3N-02185-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4034b5d1-d85e-459c-a0af-2b0f07f03342.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02185-71 (Blood Derived Normal), aliquot CPT0168650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b39f6fb-cae0-433e-85e4-4e75f7e297db

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 7, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, RNA 1, In Frame Del 1, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL3 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs200572221, COSV54439728; called by muse, mutect2, varscan2
- ANKRD24 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1055419943; called by muse, mutect2, varscan2
- APOL1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs199608929, COSV100045942; called by muse, mutect2, varscan2
- B4GALNT3 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs750120863; called by muse, mutect2, varscan2
- CDK14 | c.614C>T p.T205M (on ENST00000380050 / NM_001287135.2; = p.T187M on NM_012395.3) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769287160; called by muse, mutect2, varscan2
- EMILIN3 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1454094931; called by muse, mutect2
- ENAM | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778365039, COSV101252916; called by muse, mutect2, varscan2
- GABRA1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV50098693; called by muse, mutect2, varscan2
- HRNR | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 160/392 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs764039667; called by muse, mutect2, varscan2
- JPH3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.233); catalogued as rs146321235, COSV99414032; called by muse, mutect2, varscan2
- MAGEB16 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67874678; called by muse, mutect2
- MYC | c.877A>G p.S293G (on ENST00000377970; = p.S308G on NM_002467.6) | Missense Mutation (SNP) | VAF 653/852 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV104388344; called by muse, mutect2, varscan2
- PEAK1 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 75/103 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1441442864; called by muse, mutect2, varscan2
- RTL3 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100329789; called by muse, mutect2, varscan2
- SIGLEC11 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs1237884488; called by mutect2, varscan2
- SLFN11 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs546044791, COSV57698837; called by muse, mutect2
- TRAPPC12 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs901296240; called by muse, mutect2, varscan2
- USP30 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs200633278; called by muse, mutect2, varscan2
- ZNF318 | c.4831G>C p.D1611H | Missense Mutation (SNP) | VAF 25/446 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV58933299; called by muse, mutect2
- ADAMTS2 | c.2798C>T p.T933I | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMD | c.6376T>C p.F2126L | Missense Mutation (SNP) | VAF 90/140 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- GSPT2 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDGFL1 | c.623G>C p.S208T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HERC2 | c.3574A>G p.M1192V | Missense Mutation (SNP) | VAF 135/209 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGLON5 | c.495del p.W166Gfs*31 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | called by mutect2, pindel, varscan2
- INPP4B | c.1496A>C p.D499A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- KRT7 | c.1021_1023del p.E341del | In Frame Del (DEL) | VAF 84/192 reads (44%) | called by pindel, varscan2
- KRTAP15-1 | c.177dup p.S60Qfs*31 | Frame Shift Ins (INS) | VAF 46/133 reads (35%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.2762T>A p.L921H | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAPK13 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- METTL21C | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 88/157 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MIER1 | c.505G>A p.D169N (on ENST00000355356 / NM_001077701.3; = p.D186N on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NUP210L | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2
- OR1L3 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PINX1 | c.782T>G p.L261R | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- POT1 | c.599A>C p.D200A | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RADX | c.2384A>G p.Y795C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ROBO2 | c.1378G>C p.G460R | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC4A5 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX17 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TEAD2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TP53 | c.1028_1029del p.E343Afs*3 | Frame Shift Del (DEL) | VAF 150/270 reads (56%) | called by pindel, varscan2
- TRPM4 | c.2941G>T p.E981* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- UCP1 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- VARS2 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 210/362 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- XPO5 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZDBF2 | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF703 | c.868del p.A290Pfs*120 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | called by mutect2, pindel, varscan2
- DIDO1 | c.5577G>A p.P1859= | Silent (SNP) | VAF 115/281 reads (41%) | catalogued as rs958540208, COSV56620708; called by muse, mutect2, varscan2
- KLF6 | c.267T>A p.T89= | Silent (SNP) | VAF 159/236 reads (67%) | catalogued as rs1564296202; called by muse, mutect2, varscan2
- PSMA8 | c.93A>T p.G31= | Silent (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- SLC25A47 | c.834G>C p.L278= | Silent (SNP) | VAF 81/131 reads (62%) | called by muse, mutect2, varscan2
- TENM1 | c.1692T>G p.P564= | Silent (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- TLR5 | c.975T>C p.N325= | Silent (SNP) | VAF 186/487 reads (38%) | called by muse, mutect2, varscan2
- USP8 | c.3142T>C p.L1048= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- AL590867.2 | n.135C>T | RNA (SNP) | VAF 143/439 reads (33%) | catalogued as rs376209654; called by muse, mutect2, varscan2
- MEAK7 | c.153+437C>T | Intron (SNP) | VAF 37/88 reads (42%) | catalogued as rs746654825; called by muse, mutect2, varscan2
- REEP6 | c.*316C>T | 3'UTR (SNP) | VAF 58/162 reads (36%) | catalogued as rs1037698683, COSV99278843; called by muse, mutect2, varscan2
- SLC25A21 | c.-189C>T | 5'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- TNXB | c.2358+1688G>C | Intron (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
